MMRF case MMRF_1573 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/65990cba-9536-4c9b-bfbc-addde266b7a0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 76 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 76.0 years (27,758 days); ISS stage: II; Days to last known disease status: 1,295 days (3.5 years); Days to last follow up: 1,295 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 88 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 111 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 193 days; Days to treatment end: 196 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 195 days; Days to treatment end: 195 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 196 days; Days to treatment end: 196 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 2.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 698 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.6 mg/dL; Immunoglobulin G 34.9 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 3.74 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.73 mmol/L; Albumin 34 g/L; Total Protein 8.1 g/dL; Glucose 6 mmol/L.
- Day 88 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.24 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 2.16 g/L; Immunoglobulin M 0.67 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 6.4 g/dL; Glucose 4.57 mmol/L.
- Day 210 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.87 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 6.18 µkat/L; Hemoglobin 4.96 mmol/L; Leukocytes 3.5 ×10⁹/L; Platelets 40 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 1.98 mmol/L; Albumin 24 g/L; Total Protein 4.8 g/dL; Glucose 4.73 mmol/L.
- Day 291 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.983 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.43 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 5.28 mmol/L.
- Day 368 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 9.41 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 459 (ECOG 1): Hemoglobin 6.57 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 172 ×10⁹/L.
- Day 557 (ECOG 1): Hemoglobin 7.38 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 4.84 mmol/L.
- Day 658 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 1.45 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.28 mmol/L.
- Day 760 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 1.66 g/L; Immunoglobulin M 0.79 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.17 mmol/L.
- Day 851 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 0.8 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 4.95 mmol/L.
- Day 950 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.69 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.88 mmol/L.
- Day 1,041 (ECOG 1): Immunoglobulin G 11.9 g/L; Immunoglobulin A 1.84 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.01 mmol/L.
- Day 1,134 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 2.13 g/L; Immunoglobulin M 1.27 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 6.49 mmol/L.
- Day 1,295 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 2.14 g/L; Immunoglobulin M 0.71 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.53 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.12 mmol/L.

Other clinical attributes
- Day 1: Weight: 74 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples)
- Sample MMRF_1573_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1573_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
